CCDI case PBBXZM — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Other endocrine glands and related structures.
https://portal.gdc.cancer.gov/cases/559a657f-c17a-4afd-9923-787dabe5d0e5

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Germinoma: ICD-O-3 morphology code: 9064/3; Tissue or organ of origin: Pineal gland; Age at diagnosis: 15.7 years (5,741 days).

Biospecimens (3 samples)
- Sample 0DLBLW: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DLBME: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DLBMP: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
